Somatic mutation profile of tumor specimen MMRF_1462_1_BM_CD138pos (aliquot MMRF_1462_1_BM_CD138pos_T2_KAS5U_L02453) from MMRF case MMRF_1462, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.6 years (21,779 days).
Specimen MMRF_1462_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6303b372-1d08-4963-a9af-1618b83a4ac6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1462_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1462_1_PB_Whole_C3_KAS5U_L02464; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/783cf5c4-42e6-440c-9ad3-1672b7e0ebc3

The open-access MAF lists 140 somatic variants for this specimen: 55 protein-altering or splice-affecting, 25 silent, 60 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, 3'UTR 30, Silent 25, Intron 13, 5'UTR 8, 3'Flank 5, Nonsense Mutation 4, 5'Flank 3, Splice Site 2, Translation Start Site 2, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 13/52 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAMP | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs1248958261, COSV50307674; called by muse, mutect2, varscan2
- ARG1 | c.134G>C p.C45S | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.139); catalogued as COSV51581477; called by muse, mutect2, varscan2
- ASNSD1 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 24/233 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99641119; called by muse, mutect2, varscan2
- ATE1 | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs960328457; called by muse, mutect2, varscan2
- COL20A1 | c.3026C>T p.T1009M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs200056990, COSV100491036; called by muse, mutect2, varscan2
- DNAAF1 | c.265A>T p.T89S | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57578756; called by muse, mutect2
- DNAH2 | c.3316G>A p.E1106K | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as rs140417225; called by muse, mutect2, varscan2
- IGHV2-70D | c.53T>C p.L18S | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs1319867197; called by muse, varscan2
- IGKV5-2 | c.55A>G p.R19G | Missense Mutation (SNP) | VAF 67/76 reads (88%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs760745682; called by muse, mutect2, varscan2
- IGKV5-2 | c.145A>T p.I49F | Missense Mutation (SNP) | VAF 63/74 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs761508612; called by muse, mutect2, varscan2
- IGLL5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 22/63 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.028); catalogued as rs767386322, COSV73250551; called by muse, mutect2, varscan2
- IGLL5 | c.116T>C p.L39P | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs532234272, COSV73249744; called by muse, varscan2
- KRT35 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.555); catalogued as COSV55843023; called by muse, mutect2
- LRSAM1 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 22/197 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1006024672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MARCHF3 | c.376C>A p.P126T | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.338); catalogued as rs760059259; called by muse, mutect2, varscan2
- MYO18A | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.798); catalogued as rs887114321; called by muse, mutect2, varscan2
- NAXD | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 130/149 reads (87%) | catalogued as rs921496694, COSV57289297; called by muse, mutect2, varscan2
- PGBD5 | c.734C>T p.A245V (on ENST00000525115; = p.A314V on NM_001258311.2) | Missense Mutation (SNP) | VAF 79/147 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.272); catalogued as rs1488372662, COSV58413566; called by muse, mutect2, varscan2
- PPP1CA | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs771504128; called by muse, mutect2, varscan2
- ZNF142 | c.4631G>A p.R1544Q (on ENST00000411696 / NM_001379660.1; = p.R1344Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374554076; called by muse, mutect2, varscan2
- ZNF43 | c.532G>C p.E178Q | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.795); catalogued as COSV61685227; called by muse, mutect2, varscan2
- ACTG1 | c.101_115del p.I34_P38del | In Frame Del (DEL) | VAF 94/268 reads (35%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.2942C>A p.A981D (on ENST00000370717 / NM_001366005.1; = p.A968D on NM_012302.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by mutect2, varscan2
- ANKRD16 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ATAD2 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- CFH | c.3137C>A p.T1046N | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- CHD9 | c.4384G>C p.D1462H | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2
- CIT | c.4586C>G p.S1529C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COPA | c.283T>G p.Y95D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CRYGD | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DDIT4 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DNAI4 | c.530+2T>G p.X177_splice | Splice Site (SNP) | VAF 27/55 reads (49%) | called by muse, mutect2
- FBXL12 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GADD45A | c.146+2T>A p.X49_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | called by muse, varscan2
- GPR158 | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HACD1 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- HELZ | c.3544C>T p.Q1182* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- IGHV2-70D | c.206T>C p.L69P | Missense Mutation (SNP) | VAF 70/106 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.144); called by muse, varscan2
- IGHV2-70D | c.149C>G p.T50S | Missense Mutation (SNP) | VAF 54/66 reads (82%) | SIFT tolerated (0.68); PolyPhen benign (0.011); called by muse, varscan2
- KCNA5 | c.226C>T p.R76W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); called by muse, mutect2
- KHDRBS1 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- MBNL1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- NLN | c.1414C>G p.L472V | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- NUMA1 | c.803A>G p.Q268R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PSG11 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 54/133 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD21L1 | c.1486T>A p.S496T | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.058); called by mutect2, varscan2
- RB1CC1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2
- RBM15 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- SLC35G2 | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 57/288 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC4AP | c.1826A>G p.K609R | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- TTN | c.17105A>C p.Q5702P (on ENST00000591111; = p.Q4775P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/80 reads (40%) | PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ZNF727 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 22/165 reads (13%) | called by muse, mutect2, varscan2
- ZNF865 | c.2729C>T p.A910V | Missense Mutation (SNP) | VAF 36/63 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- ZNF91 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- C22orf39 | c.75C>T p.S25= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- CCDC62 | c.1446G>C p.L482= | Silent (SNP) | VAF 32/84 reads (38%) | called by muse, mutect2, varscan2
- CEP250 | c.721C>A p.R241= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, mutect2, varscan2
- CLEC12A | c.633C>T p.S211= | Silent (SNP) | VAF 17/171 reads (10%) | called by muse, mutect2
- DDIT4 | c.369G>A p.L123= | Silent (SNP) | VAF 40/84 reads (48%) | catalogued as rs1564804769; called by muse, mutect2, varscan2
- DISP3 | c.1639C>T p.L547= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as COSV53822452; called by muse, mutect2, varscan2
- ESYT3 | c.255C>T p.A85= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- FREM2 | c.6990G>A p.V2330= | Silent (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- HSPA8 | c.441A>C p.P147= | Silent (SNP) | VAF 21/46 reads (46%) | called by muse, mutect2, varscan2
- IGLL5 | c.153C>T p.D51= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as rs759339896, COSV104440311, COSV73249815; called by muse, varscan2
- IMPG2 | c.1681C>T p.L561= | Silent (SNP) | VAF 7/167 reads (4%) | called by muse, mutect2
- KHDRBS1 | c.561G>C p.L187= | Silent (SNP) | VAF 27/101 reads (27%) | called by muse, mutect2, varscan2
- MMP2 | c.345C>T p.R115= | Silent (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- NYAP1 | c.750C>T p.A250= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs147915491; called by muse, mutect2, varscan2
- PHF12 | c.2067C>T p.F689= | Silent (SNP) | VAF 17/94 reads (18%) | called by muse, mutect2, varscan2
- POLR2A | c.3477C>T p.C1159= | Silent (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- PUM1 | c.3207A>C p.V1069= | Silent (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- PUM1 | c.3111A>G p.V1037= | Silent (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- SNAPC4 | c.2535C>G p.L845= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV53738858; called by muse, mutect2, varscan2
- TFEC | c.1039T>C p.L347= | Silent (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- TOPORS | c.1815G>A p.Q605= | Silent (SNP) | VAF 53/391 reads (14%) | called by muse, mutect2, varscan2
- UMAD1 | c.15C>T p.F5= | Silent (SNP) | VAF 34/171 reads (20%) | called by muse, mutect2, varscan2
- ZMYM1 | c.1062C>T p.T354= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as rs146516874; called by muse, mutect2
- ZNF142 | c.3786C>A p.P1262= (on ENST00000411696 / NM_001379660.1; = p.P1062= on NM_001105537.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 7/74 reads (9%) | called by muse, mutect2, varscan2
- ZNF585B | c.2166G>A p.E722= | Silent (SNP) | VAF 16/238 reads (7%) | called by muse, mutect2
- ABHD13 | c.*3876G>A | 3'UTR (SNP) | VAF 19/23 reads (83%) | called by muse, mutect2, varscan2
- AC100868.1 | c.152-2066A>G | Intron (SNP) | VAF 11/213 reads (5%) | called by muse, mutect2
- ACOT9 | chrX:23703052 G>A | 3'Flank (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- ARL5B | c.*2893A>T | 3'UTR (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- CDKN2AIP | c.403+151C>A | Intron (SNP) | VAF 7/85 reads (8%) | called by muse, mutect2
- COL3A1 | c.*220T>C | 3'UTR (SNP) | VAF 9/98 reads (9%) | called by muse, mutect2
- CSNK1G3 | chr5:123616777 T>A | 3'Flank (SNP) | VAF 11/65 reads (17%) | called by muse, mutect2, varscan2
- DCN | c.211+1321T>C | Intron (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- DECR1 | c.*187C>T | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2
- DENND3 | c.*910G>A | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- DIO3OS | chr14:101552578 G>A | 3'Flank (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- EIF3H | c.*431C>A | 3'UTR (SNP) | VAF 21/51 reads (41%) | catalogued as rs1164480684; called by muse, mutect2, varscan2
- ELP1 | c.741-16_741-11del | Intron (DEL) | VAF 53/115 reads (46%) | called by mutect2, pindel, varscan2
- FAM76B | c.*1297T>G | 3'UTR (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- FLRT2 | c.-218A>T | 5'UTR (SNP) | VAF 5/47 reads (11%) | catalogued as rs572525412; called by muse, mutect2, varscan2
- IRAG1 | c.*1917T>C | 3'UTR (SNP) | VAF 30/65 reads (46%) | called by muse, mutect2, varscan2
- KHNYN | c.*3793C>A | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- MBOAT2 | c.*2231C>T | 3'UTR (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- MDGA1 | c.*3639G>A | 3'UTR (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- MEOX2 | c.*1158A>T | 3'UTR (SNP) | VAF 26/51 reads (51%) | called by muse, mutect2, varscan2
- MEOX2 | c.*1036T>C | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851175 T>C | 5'Flank (SNP) | VAF 72/185 reads (39%) | catalogued as rs529449665; called by muse, mutect2, varscan2
- MPIG6B | c.622-31C>A | Intron (SNP) | VAF 79/220 reads (36%) | called by muse, mutect2, varscan2
- MSRB3 | c.*2899A>T | 3'UTR (SNP) | VAF 48/104 reads (46%) | called by muse, mutect2, varscan2
- NAALADL2 | c.-4T>G | 5'UTR (SNP) | VAF 112/269 reads (42%) | called by muse, mutect2, varscan2
- NCBP2 | c.*580G>C | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- NFASC | c.*3140A>T | 3'UTR (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- OR10Z1 | chr1:158610450 T>C | 3'Flank (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- PAQR5 | chr15:69407695 A>G | 3'Flank (SNP) | VAF 4/77 reads (5%) | called by muse, mutect2
- PDGFC | c.*454T>A | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- PHKB | c.*1751A>G | 3'UTR (SNP) | VAF 66/154 reads (43%) | called by muse, mutect2, varscan2
- PIGG | c.-74G>A | 5'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2, varscan2
- PITPNB | c.*1270T>A | 3'UTR (SNP) | VAF 12/87 reads (14%) | called by muse, mutect2, varscan2
- PLA2G4C | c.1006+135T>C | Intron (SNP) | VAF 11/21 reads (52%) | called by muse, mutect2, varscan2
- POLD4 | c.-91T>C | 5'UTR (SNP) | VAF 28/55 reads (51%) | called by muse, mutect2, varscan2
- PRKAG2 | c.685-65G>A | Intron (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
- PRLR | c.*5757C>T | 3'UTR (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- RNF144A | c.*3462G>C | 3'UTR (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ROBO2 | c.-618G>T | 5'UTR (SNP) | VAF 8/49 reads (16%) | called by muse, mutect2, varscan2
- SAG | c.806+137C>T | Intron (SNP) | VAF 12/26 reads (46%) | catalogued as rs573374394; called by muse, mutect2, varscan2
- SEMA3D | c.*2934T>C | 3'UTR (SNP) | VAF 22/71 reads (31%) | called by muse, mutect2, varscan2
- SERPINB5 | c.*578T>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- SINHCAF | c.-21+2056G>A | Intron (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- SIX4 | c.*1582A>C | 3'UTR (SNP) | VAF 9/17 reads (53%) | called by muse, mutect2, varscan2
- SLC24A1 | c.2883+58C>T | Intron (SNP) | VAF 8/110 reads (7%) | called by muse, mutect2
- SMAD7 | c.*487C>T | 3'UTR (SNP) | VAF 13/55 reads (24%) | catalogued as rs945462191; called by muse, mutect2, varscan2
- SPEF2 | c.5379+517A>G | Intron (SNP) | VAF 40/380 reads (11%) | called by muse, mutect2
- SRPK2 | c.71+82084A>T | Intron (SNP) | VAF 46/110 reads (42%) | called by muse, mutect2, varscan2
- SVOP | c.*471C>T | 3'UTR (SNP) | VAF 8/108 reads (7%) | catalogued as rs1397833124; called by muse, mutect2
- TAAR3P | n.775G>C | RNA (SNP) | VAF 46/236 reads (19%) | called by muse, mutect2, varscan2
- TBXT | c.-75C>T | 5'UTR (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
- TCTEX1D2 | chr3:196318331 del GAACTGGTCGC | 5'Flank (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- TMEM150C | c.*311C>T | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- TMEM167B | chr1:109088232 A>G | 5'Flank (SNP) | VAF 20/48 reads (42%) | called by muse, mutect2, varscan2
- TMEM216 | c.*300C>T | 3'UTR (SNP) | VAF 14/248 reads (6%) | called by muse, mutect2
- TMPRSS15 | c.-139T>C | 5'UTR (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- TRPV3 | c.*969C>A | 3'UTR (SNP) | VAF 7/121 reads (6%) | called by muse, mutect2
- TSPAN5 | c.-206C>T | 5'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- UTP23 | c.188+19843C>T | Intron (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- ZCCHC10 | c.*305A>G | 3'UTR (SNP) | VAF 51/331 reads (15%) | called by muse, mutect2, varscan2
